Somatic mutation profile of tumor specimen TCGA-EJ-5503-01A (aliquot TCGA-EJ-5503-01A-01D-1576-08) from TCGA case TCGA-EJ-5503, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 50.4 years (18,395 days).
Specimen TCGA-EJ-5503-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e599fca-b113-4ca4-90aa-20bcecfc1c4e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-5503-10A (Blood Derived Normal), aliquot TCGA-EJ-5503-10A-01D-1577-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/467d9171-9c19-4ad6-9d0d-049fbf76205b

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H1-0 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 3/55 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV50649260, COSV50649420; called by muse, mutect2
- MKRN3 | c.1176G>T p.K392N | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV58810315; called by muse, mutect2
- ZNF212 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 16/302 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100242334, COSV60025339; called by muse, mutect2
